Somatic mutation profile of tumor specimen C3L-07107-01 (aliquot CPT0399130006) from CPTAC case C3L-07107, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 61.4 years (22,427 days).
Specimen C3L-07107-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a7affde-6305-47f9-b3f1-e6b722f31c11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07107-31 (Blood Derived Normal), aliquot CPT0399250002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5ca5712-92d2-428c-bf63-bb25b428f97d

The open-access MAF lists 93 somatic variants for this specimen: 69 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 23, Nonsense Mutation 2, Intron 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 33/308 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP13 | c.4426G>A p.D1476N | Missense Mutation (SNP) | VAF 37/393 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs373550260; called by muse, mutect2
- ANKDD1A | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 29/354 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs150863998; called by muse, mutect2
- CDH1 | c.767A>G p.N256S | Missense Mutation (SNP) | VAF 47/323 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV55734109, COSV55734706; called by muse, mutect2, varscan2
- CLDN8 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 48/460 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); catalogued as rs893943148, COSV54525776; called by muse, mutect2
- CNTNAP5 | c.2266C>T p.H756Y | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV70479273; called by muse, mutect2, varscan2
- CSNKA2IP | c.836A>C p.Q279P | Missense Mutation (SNP) | VAF 38/309 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV50712227; called by muse, mutect2, varscan2
- FAM184B | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 65/519 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.419); catalogued as COSV53955977; called by muse, mutect2, varscan2
- FBXW7 | c.1670G>T p.G557V (on ENST00000281708 / NM_001349798.2; = p.G477V on NM_018315.5) | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55900623; called by muse, mutect2
- FGFRL1 | c.1063G>A p.V355M | Missense Mutation (SNP) | VAF 43/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1365318430; called by muse, mutect2, varscan2
- FLI1 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 39/400 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as rs375383556; called by muse, mutect2
- GFRAL | c.300del p.K100Nfs*9 | Frame Shift Del (DEL) | VAF 23/185 reads (12%) | catalogued as rs755972268; called by mutect2, pindel, varscan2
- IGHV3OR16-13 | c.142T>G p.F48V | Missense Mutation (SNP) | VAF 46/375 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.246); catalogued as rs1293267030; called by muse, mutect2, varscan2
- KCNQ5 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 35/292 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59678539; called by muse, mutect2, varscan2
- KLK5 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 28/301 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs759653252; called by muse, mutect2, varscan2
- MEIS3 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 51/535 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs750236177, COSV100520556; called by muse, mutect2
- MRPS24 | c.283T>C p.F95L | Missense Mutation (SNP) | VAF 47/445 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs958707542; called by muse, mutect2, varscan2
- MUC16 | c.15188A>C p.K5063T | Missense Mutation (SNP) | VAF 41/400 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV67446164; called by muse, mutect2
- NCOR2 | c.5845C>G p.R1949G | Missense Mutation (SNP) | VAF 67/762 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.839); catalogued as rs781762231, COSV62297116; called by muse, mutect2
- NLRC5 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 49/417 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs370956397; called by muse, mutect2, varscan2
- PABPC4L | c.794C>A p.A265D | Missense Mutation (SNP) | VAF 38/287 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101413766; called by mutect2, varscan2
- PASK | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 42/350 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs755554702; called by muse, mutect2, varscan2
- PER1 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 42/532 reads (8%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as rs369344376, COSV57917764; called by muse, mutect2
- PHKB | c.3134T>C p.I1045T | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs200896827; called by muse, mutect2
- PNPLA7 | c.2729G>A p.R910Q | Missense Mutation (SNP) | VAF 38/505 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs1165548802; called by muse, mutect2
- PRKCG | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs372532968, COSV54724087, COSV99669453; called by muse, mutect2
- SHC2 | c.1579G>A p.G527R | Missense Mutation (SNP) | VAF 59/495 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs779103557, COSV99198957; called by muse, mutect2, varscan2
- SHISA6 | c.985C>T p.R329W (on ENST00000409168 / NM_001173461.1; = p.R380W on NM_207386.4) | Missense Mutation (SNP) | VAF 39/330 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs759642966, COSV69384484; called by muse, mutect2, varscan2
- SLC22A9 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 33/367 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs200727459; called by muse, mutect2
- TENM3 | c.7510G>A p.V2504I | Missense Mutation (SNP) | VAF 37/516 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1168499456, COSV69305824; called by muse, mutect2
- TET1 | c.4780C>T p.P1594S | Missense Mutation (SNP) | VAF 32/378 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.253); catalogued as rs1398487509; called by muse, mutect2
- TTN | c.1107G>T p.Q369H | Missense Mutation (SNP) | VAF 42/532 reads (8%) | PolyPhen benign (0.006); catalogued as COSV60017466; called by muse, mutect2
- UGGT2 | c.2702G>A p.S901N | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs374996873; called by muse, mutect2
- UHRF1 | c.1750G>A p.D584N (on ENST00000612630 / NM_001290050.1; = p.D597N on NM_013282.4) | Missense Mutation (SNP) | VAF 42/400 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53576513; called by muse, mutect2, varscan2
- VIT | c.1741G>A p.A581T (on ENST00000389975 / NM_001177969.1; = p.A596T on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/416 reads (12%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.483); catalogued as rs200598704, COSV64896862; called by muse, mutect2, varscan2
- ZNF304 | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 38/455 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.884); catalogued as rs1321790567; called by muse, mutect2
- ZNF648 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 64/512 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV60569574; called by muse, varscan2
- ZNF716 | c.610C>G p.Q204E | Missense Mutation (SNP) | VAF 41/316 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.975); catalogued as COSV101348545; called by muse, mutect2, varscan2
- ABCB1 | c.1570G>A p.V524I | Missense Mutation (SNP) | VAF 52/343 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARID5B | c.3169G>A p.A1057T | Missense Mutation (SNP) | VAF 48/419 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFH | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 22/212 reads (10%) | called by muse, mutect2, varscan2
- CSMD3 | c.7431T>G p.S2477R (on ENST00000297405 / NM_001363185.1; = p.S2373R on NM_052900.3) | Missense Mutation (SNP) | VAF 29/319 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); called by muse, mutect2
- CYP26C1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 50/443 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FAT3 | c.8607C>A p.D2869E | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FLG | c.11510C>A p.A3837D | Missense Mutation (SNP) | VAF 50/579 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- GABBR1 | c.186G>C p.E62D | Missense Mutation (SNP) | VAF 82/706 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- HERC2 | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 56/435 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- HES2 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 60/450 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IL1RL2 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.762); called by muse, mutect2
- IRAG2 | c.3318G>T p.E1106D (on ENST00000636465; = p.E151D on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KIR2DL1 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 47/640 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.403); called by muse, mutect2
- MAP3K19 | c.1692G>T p.M564I | Missense Mutation (SNP) | VAF 40/322 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MDGA1 | c.981A>C p.R327= | Splice Region (SNP) | VAF 32/266 reads (12%) | called by muse, mutect2, varscan2
- MFN2 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 33/241 reads (14%) | called by muse, mutect2, varscan2
- MTTP | c.1642T>G p.L548V | Missense Mutation (SNP) | VAF 38/406 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2
- NCAPG | c.482A>C p.Q161P | Missense Mutation (SNP) | VAF 34/344 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NUGGC | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 40/450 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.251); called by muse, mutect2
- OR56B1 | c.926C>A p.A309E | Missense Mutation (SNP) | VAF 26/333 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- OR6C76 | c.470T>G p.L157R | Missense Mutation (SNP) | VAF 32/285 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PAM | c.962A>G p.K321R | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2
- PAPPA2 | c.2266G>T p.D756Y | Missense Mutation (SNP) | VAF 40/462 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHYH | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- PPP1R3E | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 21/618 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.035); called by muse, mutect2
- RAD51AP2 | c.2681A>T p.N894I | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- SGCD | c.40C>A p.P14T (on ENST00000435422 / NM_001128209.2; = p.P15T on NM_000337.5) | Missense Mutation (SNP) | VAF 35/389 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- SOX1 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.079); called by muse, varscan2
- TRPV1 | c.1582G>A p.V528M | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.118); called by muse, mutect2
- ZFHX4 | c.5537G>T p.C1846F | Missense Mutation (SNP) | VAF 44/520 reads (8%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.033); called by muse, mutect2
- ZNF385D | c.359C>A p.S120Y | Missense Mutation (SNP) | VAF 40/452 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.261); called by muse, mutect2
- AL669918.1 | c.2052C>A p.T684= | Silent (SNP) | VAF 64/630 reads (10%) | catalogued as rs757155412, COSV71270914; called by mutect2, varscan2
- CTU1 | c.783C>T p.S261= | Silent (SNP) | VAF 38/258 reads (15%) | catalogued as rs746587816; called by muse, varscan2
- CXADR | c.864G>A p.T288= | Silent (SNP) | VAF 42/355 reads (12%) | catalogued as rs145951623; called by muse, mutect2, varscan2
- DCHS2 | c.702G>A p.P234= | Silent (SNP) | VAF 39/616 reads (6%) | catalogued as rs1470815680, COSV59719340; called by muse, mutect2
- DNAI1 | c.774A>G p.S258= | Silent (SNP) | VAF 44/360 reads (12%) | called by muse, mutect2, varscan2
- EVC | c.279G>A p.S93= | Silent (SNP) | VAF 22/281 reads (8%) | catalogued as rs373072919; called by muse, mutect2
- GSC2 | c.243G>A p.E81= | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as COSV50082439; called by muse, mutect2, varscan2
- HNRNPA0 | c.582C>T p.G194= | Silent (SNP) | VAF 70/662 reads (11%) | called by muse, mutect2, varscan2
- MACF1 | c.17787T>C p.S5929= (on ENST00000372915; = p.S3974= on NM_012090.5) | Silent (SNP) | VAF 49/330 reads (15%) | called by muse, mutect2, varscan2
- ME1 | c.1173C>G p.L391= | Silent (SNP) | VAF 23/331 reads (7%) | catalogued as COSV63839169; called by muse, mutect2
- NLGN4X | c.1149C>T p.I383= | Silent (SNP) | VAF 48/205 reads (23%) | catalogued as rs375777247, COSV99323690; called by muse, mutect2, varscan2
- P2RX6 | c.912G>A p.E304= | Silent (SNP) | VAF 28/436 reads (6%) | called by muse, mutect2
- PCDHA11 | c.1812G>A p.A604= | Silent (SNP) | VAF 50/469 reads (11%) | catalogued as rs1554164824, COSV56532473, COSV56548371; called by muse, varscan2
- PCDHGA5 | c.1452C>T p.N484= | Silent (SNP) | VAF 46/437 reads (11%) | catalogued as rs369080489; called by muse, mutect2, varscan2
- PROB1 | c.1677A>G p.P559= | Silent (SNP) | VAF 67/499 reads (13%) | called by muse, mutect2, varscan2
- PTPRE | c.102G>A p.T34= | Silent (SNP) | VAF 34/258 reads (13%) | catalogued as rs759075580, COSV99618445; called by muse, mutect2, varscan2
- RBM26 | c.378C>T p.H126= | Silent (SNP) | VAF 24/346 reads (7%) | called by muse, mutect2
- SMUG1 | c.711C>T p.L237= | Silent (SNP) | VAF 63/547 reads (12%) | catalogued as rs781217559; called by muse, mutect2
- STARD8 | c.1053A>T p.T351= | Silent (SNP) | VAF 58/334 reads (17%) | called by mutect2, varscan2
- STPG2 | c.651C>A p.G217= | Silent (SNP) | VAF 30/326 reads (9%) | called by muse, mutect2
- TRIM42 | c.231G>A p.K77= | Silent (SNP) | VAF 12/409 reads (3%) | called by muse, mutect2
- VIP | c.69T>G p.T23= | Silent (SNP) | VAF 26/336 reads (8%) | catalogued as COSV65889757; called by muse, mutect2
- VWA3B | c.1653T>C p.G551= | Silent (SNP) | VAF 29/241 reads (12%) | called by muse, mutect2, varscan2
- ZIC4 | c.-15-1190T>A | Intron (SNP) | VAF 26/261 reads (10%) | called by muse, mutect2, varscan2
